Gene-level copy-number profile of tumor specimen C3N-02146-04 from CPTAC case C3N-02146, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 69.7 years (25,450 days).
Specimen C3N-02146-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b051c4fc-3add-4422-a27e-1b4b8872bf44.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02146-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/f789ee92-306f-4d10-96c6-4062baf8899a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 17,591; copy number 2: 37,438; copy number 3: 2,017; copy number 4: 256; copy number 5: 999; copy number 6: 1; copy number 8: 91.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:430,239–441,170, 2 genes (within-gene range 0–2): RN7SL754P, AL669841.1.
- chr10:87,225,448–87,236,908, 1 gene (within-gene range 0–1): NUTM2A.
- chr19:53,389,793–53,473,936, 6 genes (within-gene range 0–1): ZNF765, RPL39P36, AC022137.2, TPM3P9, ZNF761, AC022137.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,091 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:1,428,465–17,558,909, 251 genes, copy number 5 (broad region; genes not listed).
- chr7:25,118,656–26,376,701, 21 genes, copy number 5 (within-gene range 2–5): CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, U3, TSEN15P3, AC003985.1, AC005100.1, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3, AC010677.1, SNX10, AC004540.2.
- chr8:93,029,751–114,791,929, 331 genes, copy number 5–8 (broad region; genes not listed).
- chr8:119,350,291–145,066,685, 460 genes, copy number 5 (broad region; genes not listed).
- chr17:67,717,931–68,422,731, 28 genes, copy number 5 (within-gene range 3–5): NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6.

Autosomal genes at a single copy (total copy number 1): 17,591. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
